Somatic mutation profile of tumor specimen TARGET-10-PARHEA-09A (aliquot TARGET-10-PARHEA-09A-01D) from TARGET case TARGET-10-PARHEA, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.6 years (3,873 days).
Specimen TARGET-10-PARHEA-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8807c340-be6c-4025-b9cd-cc0a58b31052.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARHEA-10A (Blood Derived Normal), aliquot TARGET-10-PARHEA-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f1c4174e-46a8-4635-a32d-b737f9461583

The open-access MAF lists 14 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 4, Nonsense Mutation 2, Intron 1, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYSLTR2 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 78/197 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs201503697; called by muse, mutect2, varscan2
- GOLGA3 | c.1369C>T p.H457Y | Missense Mutation (SNP) | VAF 61/63 reads (97%) | SIFT deleterious (0.03); PolyPhen benign (0.169); catalogued as rs781361124; called by muse, mutect2, varscan2
- LAMA1 | c.952G>A p.V318M | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.734); catalogued as rs748409752; called by muse, mutect2, varscan2
- MYOF | c.2177G>A p.R726Q | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.63); catalogued as rs41296137, COSV100825901; called by muse, mutect2, varscan2
- NR4A1 | c.492C>A p.S164R | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.111); called by muse, mutect2
- RPS6 | c.61G>T p.E21* | Nonsense Mutation (SNP) | VAF 4/49 reads (8%) | called by muse, mutect2
- SH2B3 | c.877C>T p.Q293* | Nonsense Mutation (SNP) | VAF 122/124 reads (98%) | called by muse, mutect2, varscan2
- BST1 | c.153C>T p.C51= | Silent (SNP) | VAF 11/25 reads (44%) | called by muse, mutect2, varscan2
- KSR2 | c.2007C>T p.G669= | Silent (SNP) | VAF 53/54 reads (98%) | catalogued as COSV56678389; called by muse, mutect2, varscan2
- SPDEF | c.537G>A p.A179= | Silent (SNP) | VAF 45/74 reads (61%) | catalogued as rs187034715, COSV100927716; called by muse, mutect2, varscan2
- USF3 | c.4014G>T p.L1338= | Silent (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- BLOC1S5-TXNDC5 | c.372+38988A>C | Intron (SNP) | VAF 45/106 reads (42%) | called by muse, mutect2, varscan2
- LDHA | chr11:18394596 A>G | 5'Flank (SNP) | VAF 36/96 reads (38%) | catalogued as rs1383986181; called by muse, mutect2, varscan2
- NIPSNAP1 | c.*5G>A | 3'UTR (SNP) | VAF 51/123 reads (41%) | called by muse, mutect2, varscan2
